Gene-level copy-number profile of tumor specimen ALCH-AF43-TTP1-A from ALCHEMIST case ALCH-AF43, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 73.6 years (26,892 days).
Specimen ALCH-AF43-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a80d1a3a-4574-433a-9063-76d2487e3885.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AF43-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,222 have no estimate.
https://portal.gdc.cancer.gov/files/e5f5ce7a-0b87-4811-b0da-dda5ea61241c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 11; copy number 1: 239; copy number 2: 57,730; copy number 3: 414; copy number 4: 7.

Homozygous deletions (total copy number 0; autosomes only): 11 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:15,989,871–16,034,050, 5 genes: TBC1D3P6, SRARP, AL355994.3, HSPB7, CLCNKA.
- chr9:93,951,627–93,959,140, 2 genes: BARX1, BARX1-DT.
- chr11:47,177,522–47,191,542, 3 genes: PACSIN3, MIR6745, AC090589.1.
- chr16:81,106,533–81,106,639, 1 gene (within-gene range 0–2): RNU6-1191P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 239. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
